Somatic mutation profile of tumor specimen TARGET-40-NAAGJR-01A (aliquot TARGET-40-NAAGJR-01A-01D) from TARGET case TARGET-40-NAAGJR, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.2 years (3,007 days).
Specimen TARGET-40-NAAGJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ec6cce6-a9bb-455b-bd46-0ab873806b9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJR-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91d70c3d-b937-457e-ad35-5b61e75419ae

The open-access MAF lists 92 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Intron 6, Nonsense Mutation 3, RNA 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN14 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV59771812; called by muse, mutect2
- CMYA5 | c.10546T>C p.C3516R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71406782; called by muse, mutect2, varscan2
- IFT172 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV53133343; called by muse, mutect2, varscan2
- LRRC53 | c.132T>A p.Y44* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as rs1024017824; called by muse, mutect2
- MGAT4C | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV59830096; called by muse, mutect2, varscan2
- PAPPA2 | c.1920C>A p.D640E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62773025; called by muse, mutect2, varscan2
- PGLYRP3 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51953191; called by muse, mutect2
- PRUNE2 | c.4969C>G p.L1657V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.116); catalogued as rs968760423; called by muse, mutect2, varscan2
- RPTN | c.1246A>G p.S416G | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762417902; called by muse, varscan2
- SPATA31E1 | c.3202G>A p.G1068R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as rs759936645; called by muse, mutect2, varscan2
- STAT6 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100272815; called by muse, varscan2
- USP38 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs772464317; called by muse, mutect2, varscan2
- ZNF773 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs778999095; called by muse, mutect2, varscan2
- ADCY5 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AHSA1 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOA4 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- ATP6V0A1 | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ATXN7L2 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- BRPF3 | c.3131G>C p.R1044P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCKAR | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCKAR | c.406T>A p.S136T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CIB1 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CILK1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- DMD | c.117C>A p.N39K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ENDOU | c.621C>A p.N207K (on ENST00000422538 / NM_001172439.2; = p.N166K on NM_006025.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ERAP1 | c.1711A>C p.T571P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERLIN2 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLL1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- FOXA3 | c.413T>A p.L138Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA6L6 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR85 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- GRB10 | c.1448T>C p.L483P (on ENST00000398812; = p.L437P on NM_001001549.3) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- HOXA11 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HSP90AA1 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- KIF27 | c.398T>A p.V133E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF3A | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP12 | c.2218G>C p.V740L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MUC2 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- MYH2 | c.4727C>A p.S1576Y | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- MYH2 | c.4726T>A p.S1576T | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2
- NUTM2D | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- NYAP1 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ODF3L1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- OR13C3 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2
- OVGP1 | c.1349C>A p.T450N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- P2RX6 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PCDHB2 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- PNMA8B | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2
- PRSS54 | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- PSMC3 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QRICH2 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- RNF180 | c.1002C>G p.D334E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SEPTIN4 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLITRK6 | c.705C>G p.N235K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ST18 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM132D | c.2706T>A p.D902E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBL7 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- UNC79 | c.2936T>A p.L979Q (on ENST00000393151 / NM_001346218.2; = p.L802Q on NM_020818.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- XPO4 | c.3370A>T p.T1124S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF551 | c.1577C>G p.T526S | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.226); called by muse, mutect2
- ZNF568 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF600 | c.1942A>T p.S648C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.398); called by muse, mutect2
- ZNF69 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2
- ZNF879 | c.430A>T p.T144S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CILK1 | c.807C>T p.P269= | Silent (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2
- CIT | c.2182T>C p.L728= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- COLGALT1 | c.753C>A p.A251= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- GDI1 | c.81G>A p.G27= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- GPR6 | c.357G>T p.L119= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- KRT4 | c.582C>A p.V194= | Silent (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- LRRC4C | c.237G>T p.R79= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV53434696; called by muse, mutect2
- MARCHF7 | c.1266T>C p.H422= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- NKAPL | c.975G>T p.G325= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- OR10C1 | c.327C>T p.G109= (on ENST00000622521; = p.G107= on NM_013941.3) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1454127751, COSV65822755; called by muse, mutect2, varscan2
- OR2H1 | c.321C>A p.T107= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- PKHD1 | c.8697C>T p.S2899= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- PRSS48 | c.96G>A p.Q32= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1561425729, COSV71614204; called by muse, varscan2
- RNF17 | c.3072C>A p.L1024= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55053235; called by muse, mutect2, varscan2
- RPTN | c.1245C>T p.Y415= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, varscan2
- SPATA31E1 | c.576A>G p.P192= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, varscan2
- TG | c.1836T>A p.P612= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- AL033384.1 | n.263G>A | RNA (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- EPB41L1 | c.1669-2543T>G | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- GSTA2 | c.-1C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- HBE1 | c.-267+102278G>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- LINC02448 | n.454C>G | RNA (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- RBFOX1 | c.1071+487A>G | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163900 G>C | 5'Flank (SNP) | VAF 8/104 reads (8%) | catalogued as rs778014653; called by muse, mutect2
- SEPTIN4 | c.797+16G>T | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1040G>C | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TEX10 | c.-10+329G>A | Intron (SNP) | VAF 3/27 reads (11%) | catalogued as rs1298830665; called by muse, mutect2
- TNRC18 | chr7:5427953 G>A | 5'Flank (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
